CCDI case PBCMTM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/de4f4e44-bf25-43c5-a8f7-2995c717ac68

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Small cell sarcoma: ICD-O-3 morphology code: 8803/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 13.3 years (4,865 days).

Biospecimens (3 samples)
- Sample 0DWNQX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWNSO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWNTK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
